Somatic mutation profile of tumor specimen TCGA-38-A44F-01A (aliquot TCGA-38-A44F-01A-11D-A24D-08) from TCGA case TCGA-38-A44F, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 80.9 years (29,534 days).
Specimen TCGA-38-A44F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24b01859-8a9e-4986-92fb-9956ea88fd18.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-38-A44F-10A (Blood Derived Normal), aliquot TCGA-38-A44F-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89b69526-12a8-48f2-a23c-7af1523b1124

The open-access MAF lists 14 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 5, Nonsense Mutation 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATF4 | c.139C>T p.H47Y | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); catalogued as rs948230107, COSV100307849; called by muse, mutect2, varscan2
- DNAJB1 | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 11/158 reads (7%) | catalogued as COSV99584272; called by muse, mutect2
- FAT4 | c.3760G>T p.E1254* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV67892624; called by muse, mutect2
- KRTAP5-6 | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 22/274 reads (8%) | PolyPhen benign (0.011); catalogued as rs545751292, COSV66289364; called by muse, mutect2
- PROSER1 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100613067; called by muse, mutect2
- RGS12 | c.470G>T p.C157F | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.26); catalogued as rs1330598605, COSV100376411; called by muse, mutect2
- SH3BP4 | c.1675G>A p.V559M | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as rs764165962, COSV100749334; called by muse, mutect2
- SLC50A1 | c.251T>G p.I84S | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV100310507; called by muse, mutect2, varscan2
- CCDC124 | c.648C>T p.A216= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs372508805; called by muse, mutect2, varscan2
- DENND3 | c.3193T>C p.L1065= | Silent (SNP) | VAF 5/73 reads (7%) | catalogued as rs1233407178, COSV99371713; called by muse, mutect2
- FAR2 | c.1101T>C p.Y367= | Silent (SNP) | VAF 37/276 reads (13%) | catalogued as COSV99479652; called by muse, mutect2, varscan2
- H6PD | c.1488G>A p.K496= | Silent (SNP) | VAF 23/337 reads (7%) | catalogued as rs1035729085, COSV101072525; called by muse, mutect2
- INTS5 | c.444C>T p.S148= | Silent (SNP) | VAF 9/118 reads (8%) | catalogued as COSV100399837; called by muse, mutect2
- NXF5 | n.657G>T | RNA (SNP) | VAF 10/82 reads (12%) | catalogued as COSV99534683; called by muse, mutect2, varscan2
